Gene-level copy-number profile of tumor specimen TCGA-B6-A0I8-01A from TCGA case TCGA-B6-A0I8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 46.7 years (17,073 days).
Specimen TCGA-B6-A0I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.20605d45-0b1d-4c98-a2fe-8ad7e9f81b22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0I8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate.
https://portal.gdc.cancer.gov/files/d3a6b9c9-d1d8-4560-bd1c-814f19788c39

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 1,070; copy number 2: 13,525; copy number 3: 23,459; copy number 4: 12,545; copy number 5: 4,224; copy number 6: 3,181; copy number 7: 1,520; copy number 8: 263.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,474,454–158,494,886, 2 genes (within-gene range 0–4): AL365440.1, OR10R3P.
- chr2:35,219,377–35,219,604, 1 gene: SMIM7P1.
- chr4:130,808,507–130,967,575, 3 genes: AC093831.2, AC093831.1, AC093902.1.
- chr6:46,129,989–46,146,688, 1 gene (within-gene range 0–4): ENPP4.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:87,879,473–87,880,095, 1 gene: AP000676.4.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr22:46,049,478–46,113,928, 7 genes (within-gene range 0–3): PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,783 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–247,294,941, 185 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:11,820,317–19,117,636, 76 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:62,855,068–145,066,685, 1,286 genes, copy number 7–8 (within-gene range 0–8) (broad region; genes not listed).
- chr14:58,564,146–67,816,590, 181 genes, copy number 8 (broad region; genes not listed).
- chr20:31,274,170–32,439,319, 55 genes, copy number 8 (within-gene range 6–8): DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.

Autosomal genes at a single copy (total copy number 1): 1,070. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
